Gene-level copy-number profile of tumor specimen HCM-CSHL-0459-C17-01B from HCMI case HCM-CSHL-0459-C17, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.4 years (20,980 days).
Specimen HCM-CSHL-0459-C17-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 747115dc-9169-4303-b120-b39f5b7673d3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0459-C17-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/fc9d6e8e-6d0a-4015-b5a0-263fd9763ba1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 519; copy number 1: 2,525; copy number 2: 55,745; copy number 3: 112; copy number 4: 3; copy number 5: 2; copy number 7: 2; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:131,527,675–131,536,988, 2 genes: CCDC74A, MED15P4.
- chr3:129,632,019–129,632,492, 1 gene: AC023162.1.
- chr5:149,372,174–149,375,116, 1 gene (within-gene range 0–2): AC131025.1.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr15:20,344,736–20,359,166, 1 gene: AC026495.1.
- chr18:37,273,706–37,276,572, 1 gene (within-gene range 0–2): AC090386.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,844,415–136,848,801, 1 gene, copy number 5 (within-gene range 3–5): AJM1.
- chr11:129,279–186,136, 2 genes, copy number 7 (within-gene range 2–7): AC069287.3, RNU6-447P.
- chr19:1,103,926–1,106,791, 1 gene, copy number 9: GPX4.
- chr21:12,999,676–13,016,692, 1 gene, copy number 5: AP001464.1.

Autosomal genes at a single copy (total copy number 1): 181. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
